Somatic mutation profile of tumor specimen MMRF_1794_1_BM_CD138pos (aliquot MMRF_1794_1_BM_CD138pos_T1_KBS5U_L06443) from MMRF case MMRF_1794, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.5 years (29,052 days).
Specimen MMRF_1794_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 272e91a9-5c1c-400f-94ca-7ebdb8e0b3a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1794_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1794_1_PB_Whole_C2_KBS5U_L06491; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abb26087-09a8-443a-b311-5bea9d0fffa6

The open-access MAF lists 106 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 39, Missense Mutation 27, Silent 12, Intron 11, 5'UTR 6, 3'Flank 3, Nonsense Mutation 2, Frame Shift Del 2, RNA 2, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF1 | c.4250A>T p.H1417L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.13); catalogued as rs1271022707; called by muse, mutect2, varscan2
- EPHA6 | c.2470C>A p.P824T (on ENST00000389672 / NM_001080448.3; = p.P216T on NM_173655.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.763); catalogued as COSV67558449, COSV67576518; called by muse, mutect2, varscan2
- HACD2 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.046); catalogued as rs958343304; called by muse, mutect2
- JADE1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.138); catalogued as rs201834567; called by muse, mutect2, varscan2
- RPGRIP1L | c.2153-1G>A p.X718_splice | Splice Site (SNP) | VAF 14/221 reads (6%) | catalogued as COSV50916496; called by muse, mutect2
- UGT2B7 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1299487099; called by muse, mutect2, varscan2
- AGR2 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); called by mutect2, varscan2
- AP1S1 | c.92T>C p.M31T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B2 | c.2692T>A p.Y898N (on ENST00000672630; = p.Y865N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- COL4A2 | c.2725A>T p.I909F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.727); called by mutect2, varscan2
- COL6A3 | c.8654C>T p.T2885I | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND6B | c.853del p.S285Pfs*8 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- DIS3 | c.2720T>G p.V907G | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EPS8L1 | c.598A>G p.I200V (on ENST00000201647 / NM_133180.3; = p.I73V on NM_017729.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GDPD2 | c.1065C>A p.D355E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GINS1 | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ITGAX | c.3310A>C p.N1104H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- KCNAB2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2
- NCOR1 | c.6944C>T p.S2315L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- NIPBL | c.4921G>A p.V1641I | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PABPC1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDH8 | c.954C>G p.D318E | Missense Mutation (SNP) | VAF 63/70 reads (90%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLCH1 | c.3663T>A p.S1221R (on ENST00000340059 / NM_001130960.2; = p.S1213R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR2 | c.8119G>T p.D2707Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SHROOM4 | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SLC25A24 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SLC38A8 | c.724A>T p.M242L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMOX | c.1212G>A p.W404* | Nonsense Mutation (SNP) | VAF 68/189 reads (36%) | called by muse, mutect2
- TCL1A | c.67_71del p.K23Rfs*20 | Frame Shift Del (DEL) | VAF 42/125 reads (34%) | called by mutect2, pindel*, varscan2
- UBXN11 | c.1489C>T p.P497S (on ENST00000374221 / NM_183008.2; = p.P464S on NM_145345.2) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF292 | c.3967C>T p.Q1323* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- CFAP94 | c.1014A>C p.I338= (on ENST00000320267 / NM_001352064.2; = p.I344= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- F8 | c.5913C>T p.N1971= | Silent (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- GZF1 | c.1236C>T p.C412= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs1359334884, COSV57637017; called by muse, mutect2, varscan2
- KDELR1 | c.318G>T p.A106= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV58101622; called by muse, mutect2, varscan2
- MAP4K4 | c.87A>G p.E29= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- NTN3 | c.171C>T p.S57= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- PFKL | c.555C>A p.I185= | Silent (SNP) | VAF 79/228 reads (35%) | catalogued as rs1217775994; called by muse, mutect2, varscan2
- PPIP5K2 | c.1752G>A p.L584= | Silent (SNP) | VAF 43/67 reads (64%) | called by muse, mutect2, varscan2
- RORC | c.327G>A p.K109= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs376651505; called by muse, mutect2, varscan2
- SARDH | c.888C>T p.V296= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs371310169; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPCS1 | c.30C>G p.T10= | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- TGFBI | c.475C>T p.L159= | Silent (SNP) | VAF 24/32 reads (75%) | called by muse, mutect2
- ACTR3C | chr7:150246240 G>A | 3'Flank (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25167247 A>G | 3'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ARL4C | c.*1258G>A | 3'UTR (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- ASAP3 | c.*622T>A | 3'UTR (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- BHMT | c.*150C>A | 3'UTR (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- BMP3 | c.-26C>T | 5'UTR (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- BMP6 | c.*981T>C | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- C3orf14 | chr3:62335925 del A | 3'Flank (DEL) | VAF 22/60 reads (37%) | catalogued as rs905475726; called by mutect2, varscan2
- CADPS | c.2600-49A>T | Intron (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- CD93 | c.-128C>T | 5'UTR (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- CDC42EP3 | c.*3070C>G | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- CERS6 | c.*3426A>T | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- CSNK1E | c.885+847A>C | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.*409G>T | 3'UTR (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- DDX59 | c.*114A>G | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- DENND5B | c.*2881T>A | 3'UTR (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- DGCR8 | c.-222C>A | 5'UTR (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- EIF3F | c.*5832A>G | 3'UTR (SNP) | VAF 13/41 reads (32%) | catalogued as rs544645379; called by mutect2, varscan2
- F11 | c.485+474G>T | Intron (SNP) | VAF 17/56 reads (30%) | catalogued as rs529139346; called by muse, mutect2, varscan2
- FABP2 | c.*879G>A | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- FBN1 | c.164+2284C>A | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2
- FCMR | chr1:206921955 G>C | 5'Flank (SNP) | VAF 19/274 reads (7%) | called by muse, mutect2
- G3BP2 | c.*2185C>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, varscan2
- HMGA2 | c.282+5219C>A | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- IL1RL2 | c.*664C>A | 3'UTR (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- JAZF1 | c.*1365C>T | 3'UTR (SNP) | VAF 44/101 reads (44%) | catalogued as rs1025322129, COSV99386542; called by muse, mutect2, varscan2
- KIAA1143 | c.*3642T>A | 3'UTR (SNP) | VAF 85/222 reads (38%) | called by muse, mutect2, varscan2
- KIF2B | c.*11G>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | catalogued as rs766692378, COSV99275563, COSV99275657; called by muse, mutect2, varscan2
- KLF12 | c.*667T>C | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- LINC02693 | n.2773G>A | RNA (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- LRRC8B | c.*1862T>C | 3'UTR (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- LUM | c.*868G>T | 3'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as rs1173606636; called by muse, mutect2, varscan2
- LUM | c.*867G>C | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- LY6D | c.*177A>G | 3'UTR (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- MFSD9 | c.*950C>T | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- NAA30 | c.*2620A>T | 3'UTR (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- NAGK | c.30-853A>C | Intron (SNP) | VAF 15/25 reads (60%) | called by muse, varscan2
- NHLRC2 | c.*2950dup | 3'UTR (INS) | VAF 34/73 reads (47%) | catalogued as rs972592277; called by mutect2, varscan2
- NUP50 | c.*2903A>G | 3'UTR (SNP) | VAF 63/123 reads (51%) | called by muse, mutect2, varscan2
- PHF3 | c.3100-82_3100-72del | Intron (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- PLCXD3 | c.*4326A>T | 3'UTR (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- PNISR | c.*2027G>A | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PPP1R12A | c.-21+134G>T | Intron (SNP) | VAF 22/87 reads (25%) | catalogued as rs1017795200, COSV54108482, COSV54113815; called by muse, mutect2, varscan2
- PRDM1 | c.-54C>G | 5'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- PROP1 | c.*465T>A | 3'UTR (SNP) | VAF 13/19 reads (68%) | called by mutect2, varscan2
- PTPRR | c.*974T>A | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- RARRES2P6 | n.337C>T | RNA (SNP) | VAF 32/49 reads (65%) | catalogued as rs35896479; called by muse, mutect2, varscan2
- RPGR | c.2520+1582C>G | Intron (SNP) | VAF 45/49 reads (92%) | called by muse, mutect2, varscan2
- RPS24 | c.390+634T>G | Intron (SNP) | VAF 39/81 reads (48%) | called by muse, varscan2
- SCOC | c.*1398del | 3'UTR (DEL) | VAF 8/99 reads (8%) | called by mutect2, pindel
- SLC15A5 | c.*863G>A | 3'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs1346295448; called by muse, mutect2, varscan2
- SPRYD7 | c.-93G>T | 5'UTR (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- THAP11 | c.*331A>T | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- THBS2 | c.*1667C>T | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- TMEM249 | c.-82T>A | 5'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- TRPM8 | c.2761+65C>T | Intron (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- TXNIP | c.*528_*530del | 3'UTR (DEL) | VAF 8/80 reads (10%) | called by pindel, varscan2
- UBN2 | c.*733G>C | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*1297T>A | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- ZDHHC21 | c.*1963G>T | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- ZNF22 | c.*272G>A | 3'UTR (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- ZNF829 | c.*2983T>A | 3'UTR (SNP) | VAF 62/166 reads (37%) | called by muse, mutect2, varscan2
